Somatic mutation profile of tumor specimen TARGET-10-PAPGLD-09A (aliquot TARGET-10-PAPGLD-09A-01D) from TARGET case TARGET-10-PAPGLD, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.2 years (2,279 days).
Specimen TARGET-10-PAPGLD-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ffecb9ec-9133-4996-b28b-9d6dca4ca2ff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPGLD-10A (Blood Derived Normal), aliquot TARGET-10-PAPGLD-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5094d59c-bd90-46d4-96cf-3b199d5cc5e5

The open-access MAF lists 18 somatic variants for this specimen: 15 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 2, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAM135B | c.876G>T p.M292I | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs1450722812; called by muse, mutect2
- FAT3 | c.6130C>T p.R2044C | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756956581, COSV53076824; called by muse, mutect2, varscan2
- KANK4 | c.1105G>T p.A369S | Missense Mutation (SNP) | VAF 47/144 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.086); catalogued as rs768599938, COSV62985323; called by muse, mutect2, varscan2
- KCNJ11 | c.674G>T p.S225I | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); catalogued as COSV60595191; called by muse, mutect2
- MYH8 | c.4738G>T p.A1580S | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.062); catalogued as rs181695343, COSV67970448; called by mutect2, varscan2
- PAX5 | c.547G>A p.G183S | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs398123063, CM139173, COSV63911050, COSV63911644; ClinVar: risk factor; called by mutect2, varscan2
- SPTBN2 | c.4462C>T p.R1488C | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV59449755; called by muse, mutect2
- A2M | c.2370G>T p.Q790H | Missense Mutation (SNP) | VAF 84/262 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FBXO30 | c.2065G>T p.V689F | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2
- IKZF3 | c.359G>A p.C120Y | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PGBD4 | c.911C>A p.S304* | Nonsense Mutation (SNP) | VAF 3/27 reads (11%) | called by muse, mutect2
- SYNM | c.1034C>A p.T345N | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- TENM3 | c.3038G>T p.G1013V | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TSEN54 | c.166C>A p.R56S | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.297); called by muse, mutect2
- USP33 | c.2355G>T p.M785I | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.58); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- APOB | c.2982G>A p.P994= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as rs747125412; called by muse, mutect2, varscan2
- ZNF19 | c.915G>A p.E305= | Silent (SNP) | VAF 48/94 reads (51%) | called by muse, varscan2
- TMEM51 | c.-267+14750C>A | Intron (SNP) | VAF 5/60 reads (8%) | called by muse, mutect2
